Somatic mutation profile of tumor specimen MMRF_1392_1_BM_CD138pos (aliquot MMRF_1392_1_BM_CD138pos_T1_KAS5U_L01702) from MMRF case MMRF_1392, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.7 years (15,247 days).
Specimen MMRF_1392_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86547528-ec30-432b-87be-17500b96eac7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1392_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1392_1_PB_Whole_C2_KAS5U_L01710; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0999fa39-baa1-4755-a59b-d9d07ef0eff3

The open-access MAF lists 56 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 12, Silent 9, Intron 8, 3'Flank 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777164, CM1310653, COSV59758318, COSV59758899; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALOX15 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750193083; called by muse, mutect2, varscan2
- ARID1B | c.6623G>A p.R2208Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1302430069, COSV51659324, COSV51668662; ClinVar: uncertain significance; called by muse, mutect2
- BAG6 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs537092798; called by muse, mutect2, varscan2
- FAM187B | c.494A>T p.Y165F | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV100219969; called by muse, mutect2
- H1-4 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs368598196; called by muse, mutect2, varscan2
- IGHJ4 | c.10T>G p.Y4D | Missense Mutation (SNP) | VAF 45/45 reads (100%) | PolyPhen benign (0.103); catalogued as rs367800003; called by muse, mutect2, varscan2
- IGHV2-70 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373749501; called by muse, mutect2, varscan2
- IGHV4-34 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs765850603; called by muse, varscan2
- IGKJ4 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 54/56 reads (96%) | PolyPhen probably damaging (0.982); catalogued as rs778004192; called by muse, varscan2
- IGLL5 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 20/20 reads (100%) | catalogued as rs761059843, COSV73249808; called by muse, mutect2, varscan2
- KIF26B | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748801389; called by muse, mutect2, varscan2
- MYADM | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 117/572 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs763442113, COSV61240768, COSV61240936; called by muse, mutect2, varscan2
- MYO7A | c.3595G>A p.V1199M | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782151104, COSV68683761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROBO2 | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 81/119 reads (68%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs764507168; called by muse, mutect2, varscan2
- TRIM33 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs371685549; called by muse, mutect2, varscan2
- ASAP1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATR | c.3170A>G p.K1057R | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.053); called by muse, mutect2
- CEP55 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA4L | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NBEAL2 | c.7034G>T p.R2345L | Missense Mutation (SNP) | VAF 107/167 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB6 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC18A3 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRCAP | c.2695A>G p.K899E | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTC39A | c.580A>C p.S194R (on ENST00000447632 / NM_001297665.1; = p.S159R on NM_001080494.3) | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ATR | c.2610T>C p.I870= | Silent (SNP) | VAF 70/119 reads (59%) | called by muse, mutect2, varscan2
- C17orf49 | c.354C>G p.P118= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV66081121; called by muse, varscan2
- IGHV4-34 | c.88C>T p.L30= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs587760350; called by muse, mutect2, varscan2
- NLRP9 | c.489A>G p.R163= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- PFN2 | c.204G>A p.A68= | Silent (SNP) | VAF 164/625 reads (26%) | catalogued as COSV53523890; called by muse, mutect2, varscan2
- PFN4 | c.192G>T p.L64= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- SCG2 | c.1257T>G p.P419= | Silent (SNP) | VAF 111/111 reads (100%) | called by muse, mutect2, varscan2
- SLC38A3 | c.885C>T p.F295= | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as rs587729027, COSV68844170; called by muse, mutect2, varscan2
- USP5 | c.1404G>A p.K468= | Silent (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- ACADSB | c.*3523A>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ACTG1 | c.-146C>G | 5'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, varscan2
- BTLA | c.*1893_*1898del | 3'UTR (DEL) | VAF 18/146 reads (12%) | called by pindel, varscan2
- CNTN5 | c.2730+460dup | Intron (INS) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- DACH2 | c.1751-1224A>C | Intron (SNP) | VAF 14/16 reads (88%) | called by muse, mutect2, varscan2
- FAM227B | c.1013-51163G>A | Intron (SNP) | VAF 75/412 reads (18%) | called by muse, mutect2, varscan2
- FLT3LG | c.342+120G>A | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as rs1191225506; called by muse, mutect2, varscan2
- GJA1 | c.*1103del | 3'UTR (DEL) | VAF 23/50 reads (46%) | catalogued as rs1312670447; called by mutect2, pindel, varscan2
- JAML | c.44-232A>G | Intron (SNP) | VAF 83/134 reads (62%) | called by muse, mutect2, varscan2
- LPP | c.*1946_*1950del | 3'UTR (DEL) | VAF 25/87 reads (29%) | called by pindel, varscan2
- LTB | c.163-131C>G | Intron (SNP) | VAF 83/180 reads (46%) | called by muse, mutect2, varscan2
- MTR | c.*2775dup | 3'UTR (INS) | VAF 22/80 reads (28%) | called by pindel, varscan2
- MYD88 | c.464-71G>A | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2
- NPR3 | c.*4645T>C | 3'UTR (SNP) | VAF 89/192 reads (46%) | called by muse, mutect2, varscan2
- PLLP | chr16:57253313 C>T | 3'Flank (SNP) | VAF 57/113 reads (50%) | called by muse, mutect2, varscan2
- RAI14 | c.*286C>G | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- SLFN13 | c.*2170G>A | 3'UTR (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- SPCS3 | c.*3795_*3802del | 3'UTR (DEL) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- SRSF3 | c.381-46A>C | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, varscan2
- TECPR2 | c.*1829A>G | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- VAMP1 | c.*2045T>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- ZNF569 | c.*720A>G | 3'UTR (SNP) | VAF 103/212 reads (49%) | called by muse, mutect2, varscan2
